Surgical pathology report (de-identified scan), TCGA case TCGA-BR-6457, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-6457-01A (Primary Tumor).

[page 1 of 2]
Formatted Path Report

STOMACH TISSUE CHECKLIST

Specimen type: Total gastrectomy
Tumor site: Stomach
Tumor size: 7 x 0 x 7.5 cm
Tumor features: Ulcerated
Histologic type: Adenocarcinoma
Histologic grade: Poorly differentiated
Tumor extent: Subserosa
Lymph nodes: 0/15 positive for metastasis (Greater and lesser curvature 0/15)
Lymphatic invasion: Not specified
Venous invasion: Present
Perineural invasion: Not specified
Margins: Uninvolved
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: None

[page 2 of 2]
Date of Procurement

Source: NCI Genomic Data Commons file 53693bb8-138e-4fc1-898f-c0bb3cefb202 (TCGA-BR-6457.A86439DE-3AB5-4267-9721-3F198013F5DA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).